Somatic mutation profile of tumor specimen TCGA-CV-7097-01A (aliquot TCGA-CV-7097-01A-11D-2012-08) from TCGA case TCGA-CV-7097, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 53.1 years (19,382 days).
Specimen TCGA-CV-7097-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dfa26232-0bd4-4de8-95c1-762136f07f55.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-7097-10A (Blood Derived Normal), aliquot TCGA-CV-7097-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f72eb04e-582f-4524-b2d0-bfa2992de5b9

The open-access MAF lists 81 somatic variants for this specimen: 60 protein-altering or splice-affecting, 21 silent.
By variant classification: Missense Mutation 44, Silent 21, Nonsense Mutation 6, Frame Shift Del 6, Frame Shift Ins 3, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.993+2_993+13del p.X331_splice | Splice Site (DEL) | VAF 20/54 reads (37%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- ACAD10 | c.1105C>G p.L369V | Missense Mutation (SNP) | VAF 49/206 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.031); catalogued as COSV100563863; called by muse, mutect2, varscan2
- ADAMTS20 | c.4543C>T p.Q1515* | Nonsense Mutation (SNP) | VAF 22/90 reads (24%) | catalogued as COSV101238988, COSV67131277; called by muse, mutect2, varscan2
- AMY2B | c.386C>T p.T129I | Missense Mutation (SNP) | VAF 124/568 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.265); catalogued as COSV100796199; called by muse, varscan2
- BRCA1 | c.4474G>A p.G1492R | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as COSV100523415; called by muse, mutect2, varscan2
- BTLA | c.247G>T p.E83* | Nonsense Mutation (SNP) | VAF 22/128 reads (17%) | catalogued as COSV100569616; called by muse, mutect2, varscan2
- CHST6 | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.044); catalogued as rs570082634, COSV59999934; called by muse, mutect2, varscan2
- DACT1 | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.292); catalogued as COSV100241624, COSV60020889; called by muse, mutect2, varscan2
- DCAF7 | c.727G>A p.D243N | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.32); catalogued as COSV100177544; called by muse, mutect2, varscan2
- DCN | c.568G>C p.G190R | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99029717, COSV99271860; called by muse, mutect2
- DDC | c.399G>C p.L133F | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100779140; called by muse, mutect2, varscan2
- DNAH10 | c.12919G>T p.V4307L (on ENST00000409039; = p.V4246L on NM_207437.3) | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV99435262; called by muse, mutect2, varscan2
- DNAH6 | c.1702A>G p.I568V | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.05); catalogued as COSV99405123; called by muse, mutect2, varscan2
- DOT1L | c.1838C>T p.T613M | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs756254147, COSV101288526; called by muse, mutect2, varscan2
- DYNC2I1 | c.1267A>T p.I423F | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV101337613; called by muse, mutect2, varscan2
- FSIP2 | c.16738G>A p.D5580N | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV100554210; called by muse, mutect2, varscan2
- FYB2 | c.698G>A p.S233N | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.116); catalogued as rs1168517723, COSV100599269; called by muse, mutect2, varscan2
- GUCY1A1 | c.1547A>T p.Q516L | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.501); catalogued as COSV99637245; called by muse, mutect2, varscan2
- HDAC4 | c.2956G>T p.E986* | Nonsense Mutation (SNP) | VAF 34/82 reads (41%) | catalogued as COSV100612769; called by muse, mutect2, varscan2
- HSD3B1 | c.118G>A p.G40R | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs141328314, COSV52492600; called by muse, varscan2
- HTR1F | c.473C>T p.P158L | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1271444839, COSV100137972; called by muse, mutect2, varscan2
- HUS1B | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs771421496, COSV100032994; called by muse, mutect2, varscan2
- IL26 | c.451A>C p.K151Q | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV99970805; called by muse, mutect2, varscan2
- LGR6 | c.649T>G p.L217V (on ENST00000367278 / NM_001017403.1; = p.L165V on NM_021636.3) | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99706225; called by muse, mutect2, varscan2
- LILRB1 | c.1264C>T p.P422S (on ENST00000427581; = p.P386S on NM_006669.6) | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.8); catalogued as COSV100206976, COSV99048735; called by muse, varscan2
- LMAN1L | c.1144del p.V382Sfs*18 | Frame Shift Del (DEL) | VAF 5/57 reads (9%) | catalogued as COSV59001781; called by mutect2, pindel
- LTK | c.1828G>A p.G610S | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.206); catalogued as COSV99540618; called by muse, mutect2, varscan2
- MCM3AP | c.5434A>G p.I1812V | Missense Mutation (SNP) | VAF 49/141 reads (35%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV99386539; called by muse, mutect2, varscan2
- NCOA1 | c.1633A>G p.N545D | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as COSV99945326; called by mutect2, varscan2
- OR51B2 | c.83C>T p.P28L | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.039); catalogued as COSV60916906; called by muse, mutect2, varscan2
- OR52N1 | c.349C>G p.L117V | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100398612; called by muse, mutect2, varscan2
- OR5T2 | c.686C>G p.S229C | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100506828; called by muse, mutect2, varscan2
- PCDHA12 | c.1507G>A p.A503T | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.037); catalogued as rs1554169178, COSV100248065; called by muse, mutect2
- PTGR2 | c.70C>T p.R24* | Nonsense Mutation (SNP) | VAF 24/65 reads (37%) | catalogued as rs376183153; called by muse, varscan2
- RFX6 | c.831C>A p.D277E | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100263365; called by muse, mutect2, varscan2
- RIMS4 | c.386A>T p.Q129L | Missense Mutation (SNP) | VAF 79/151 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV100865078; called by muse, mutect2, varscan2
- RPH3A | c.697G>A p.V233M (on ENST00000389385 / NM_001143854.2; = p.V229M on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs758294722, COSV101231777; called by muse, mutect2, varscan2
- SEMA4B | c.2046A>T p.Q682H | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV100153229; called by muse, mutect2, varscan2
- SERBP1 | c.726A>G p.I242M | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as COSV100769054; called by muse, mutect2, varscan2
- SMAD1 | c.87G>A p.W29* | Nonsense Mutation (SNP) | VAF 5/57 reads (9%) | catalogued as COSV100129637; called by muse, mutect2
- SMAD4 | c.1381C>T p.Q461* | Nonsense Mutation (SNP) | VAF 12/35 reads (34%) | catalogued as COSV100747512; called by muse, mutect2, varscan2
- SOAT2 | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.125); catalogued as COSV100037373; called by muse, mutect2, varscan2
- SPRYD3 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.037); catalogued as COSV100036579; called by muse, mutect2, varscan2
- STXBP5L | c.2023A>G p.S675G | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.182); catalogued as COSV99872359; called by muse, mutect2, varscan2
- TBXT | c.1286C>A p.P429H | Missense Mutation (SNP) | VAF 16/212 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as COSV99752128; called by muse, mutect2
- TRPV6 | c.2272G>A p.G758R | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.029); catalogued as rs757082631, COSV100844147; called by muse, mutect2, varscan2
- TTN | c.16714G>A p.D5572N (on ENST00000591111; = p.D4645N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 94/286 reads (33%) | PolyPhen probably damaging (0.964); catalogued as COSV100597276; called by muse, mutect2, varscan2
- VEZT | c.41C>A p.S14Y | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99703517, COSV99704061; called by muse, mutect2, varscan2
- XCR1 | c.995T>C p.F332S | Missense Mutation (SNP) | VAF 14/19 reads (74%) | SIFT deleterious (0.04); PolyPhen benign (0.155); catalogued as COSV100499300; called by muse, mutect2
- ZNF124 | c.773G>C p.G258A (on ENST00000543802 / NM_001297568.1; = p.G196A on NM_003431.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); catalogued as COSV100517660; called by muse, mutect2, varscan2
- ZNF708 | c.834A>C p.K278N | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as COSV100803044; called by muse, mutect2, varscan2
- ZRSR2 | c.43C>A p.H15N | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as COSV100314978; called by muse, mutect2, varscan2
- ABCF1 | c.1132dup p.Q378Pfs*7 (on ENST00000326195 / NM_001025091.2; = p.Q340Pfs*7 on NM_001090.3) | Frame Shift Ins (INS) | VAF 16/69 reads (23%) | called by mutect2, pindel, varscan2
- CBR4 | c.308_309insAG p.L104Gfs*11 | Frame Shift Ins (INS) | VAF 9/177 reads (5%) | called by muse*, mutect2
- DDX27 | c.1819_1828del p.E607Cfs*7 | Frame Shift Del (DEL) | VAF 18/55 reads (33%) | called by mutect2, pindel, varscan2
- GALNT17 | c.136_137del p.A46Rfs*43 | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | called by pindel, varscan2
- NAPA | c.462dup p.E155Rfs*29 | Frame Shift Ins (INS) | VAF 14/62 reads (23%) | called by mutect2, pindel, varscan2
- PAF1 | c.1261del p.E421Rfs*137 | Frame Shift Del (DEL) | VAF 31/251 reads (12%) | called by mutect2, pindel, varscan2
- PLD1 | c.2315del p.N772Tfs*14 | Frame Shift Del (DEL) | VAF 15/90 reads (17%) | called by mutect2, pindel, varscan2
- SYNJ2 | c.4448del p.K1483Rfs*16 | Frame Shift Del (DEL) | VAF 17/63 reads (27%) | called by mutect2, pindel, varscan2
- ANO8 | c.2754C>T p.A918= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as COSV99344128; called by muse, mutect2
- CDYL2 | c.582C>T p.D194= | Silent (SNP) | VAF 17/80 reads (21%) | catalogued as rs149647231; called by muse, mutect2, varscan2
- CIITA | c.3207G>A p.P1069= | Silent (SNP) | VAF 40/196 reads (20%) | catalogued as rs772387879, COSV100161461; called by muse, mutect2, varscan2
- CNTRL | c.2836A>C p.R946= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV99441291; called by muse, mutect2, varscan2
- CPNE4 | c.1665A>G p.L555= | Silent (SNP) | VAF 17/67 reads (25%) | catalogued as rs770399710, COSV101456591; called by muse, mutect2, varscan2
- DMRT3 | c.468A>G p.E156= | Silent (SNP) | VAF 11/94 reads (12%) | catalogued as rs781176158, COSV99505672; called by muse, mutect2, varscan2
- FBXO8 | c.486C>A p.I162= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV101183628; called by muse, mutect2, varscan2
- HLA-DMA | c.765G>A p.R255= | Silent (SNP) | VAF 21/72 reads (29%) | catalogued as COSV100877656; called by muse, mutect2, varscan2
- JADE1 | c.850C>T p.L284= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV99885349; called by muse, mutect2, varscan2
- KCNMB1 | c.165G>T p.L55= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs143181866; called by muse, mutect2, varscan2
- KIF17 | c.1881C>T p.S627= | Silent (SNP) | VAF 37/117 reads (32%) | catalogued as rs1553150562, COSV99928622; called by muse, mutect2, varscan2
- MPZL3 | c.318A>G p.V106= | Silent (SNP) | VAF 65/142 reads (46%) | catalogued as COSV99636163; called by muse, mutect2, varscan2
- MUC17 | c.3087T>C p.G1029= | Silent (SNP) | VAF 180/653 reads (28%) | catalogued as COSV100071851; called by muse, mutect2, varscan2
- MYH2 | c.1683C>G p.G561= | Silent (SNP) | VAF 9/147 reads (6%) | catalogued as COSV99819384; called by muse, mutect2
- ODF2 | c.501C>T p.H167= (on ENST00000434106 / NM_153433.2; = p.H143= on NM_002540.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 33/78 reads (42%) | catalogued as rs1319957124, COSV63548846; called by muse, mutect2, varscan2
- PEAR1 | c.195C>T p.C65= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as rs1374648304, COSV52771358; called by muse, mutect2, varscan2
- PLXND1 | c.729G>A p.L243= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as rs1345940212, COSV100139132; called by muse, mutect2, varscan2
- RBPJL | c.1359C>A p.I453= | Silent (SNP) | VAF 31/71 reads (44%) | catalogued as COSV100643443; called by muse, mutect2, varscan2
- TECPR2 | c.468G>C p.L156= | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as COSV100849847; called by muse, mutect2, varscan2
- ZNF224 | c.384T>A p.G128= | Silent (SNP) | VAF 11/78 reads (14%) | catalogued as COSV100425317; called by muse, mutect2, varscan2
- ZNF318 | c.6678T>C p.D2226= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as COSV100545979; called by muse, mutect2, varscan2
